Gene-level copy-number profile of tumor specimen ALCH-B01D-TTP1-A from ALCHEMIST case ALCH-B01D, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.9 years (23,352 days).
Specimen ALCH-B01D-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 63e4f53b-e7b4-4c69-a6a8-9c2203ab3a4d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B01D-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/df5252df-63a6-46a9-b07e-32fcdb2e8b9e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 120; copy number 1: 17,763; copy number 2: 36,942; copy number 3: 3,626; copy number 4: 382; copy number 5: 1; copy number 7: 14; copy number 8: 1; copy number 15: 19; copy number 16: 14; copy number 27: 31.

Homozygous deletions (total copy number 0; autosomes only): 104 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:10,639,241–10,654,333, 1 gene (within-gene range 0–1): AL139423.1.
- chr2:87,194,786–87,194,859, 1 gene (within-gene range 0–2): MIR4771-1.
- chr3:48,564,073–48,672,733, 10 genes: COL7A1, MIR711, UQCRC1, TMEM89, SLC26A6, MIR6824, CELSR3, MIR4793, LINC02585, AC141002.1.
- chr4:49,579,833–49,589,529, 2 genes: AC119751.4, SNX18P25.
- chr6:31,971,091–32,041,644, 9 genes (within-gene range 0–2): STK19, C4A, C4A-AS1, CYP21A1P, TNXA, STK19B, C4B, C4B-AS1, CYP21A2.
- chr7:4,811,188–4,811,289, 1 gene (within-gene range 0–2): Y_RNA.
- chr8:11,761,256–12,665,588, 49 genes (within-gene range 0–1): C8orf49, NEIL2, SUB1P1, FDFT1, AC069185.1, CTSB, AC025857.1, OR7E158P, OR7E161P, DEFB136, DEFB135, DEFB134, AC107918.3, DEFB131E, AC107918.2, AC107918.1, DEFB131C, DEFB130B, RNA5SP253, DEFB108D, ZNF705D, FAM66D, AC130366.1, USP17L7, USP17L2, DEFB109D, FAM90A2P, ALG1L11P, FAM86B1, AC145124.1, ENPP7P12, DEFB131D, DEFB130A, RNA5SP254, DEFB108E, ZNF705CP, FAM66A, AC087203.1, AC087203.2, DEFB109A, AC087203.3, FAM90A25P, ALG1L12P, FAM86B2, ENPP7P6, AC068587.4, AC130352.1, RPS3AP34, AC068587.2.
- chr10:49,296,112–49,327,492, 2 genes: C10orf71-AS1, C10orf71.
- chr10:86,654,547–86,666,848, 1 gene: OPN4.
- chr11:64,035,970–64,103,653, 2 genes (within-gene range 0–2): AP000721.2, AP006333.2.
- chr11:73,307,235–73,397,474, 4 genes: AP002761.3, ARHGEF17, RELT, AP000763.4.
- chr12:123,470,054–123,536,534, 4 genes (within-gene range 0–1): RILPL1, AC145423.1, AC145423.2, MIR3908.
- chr14:100,319,073–100,330,421, 2 genes: RN7SL523P, SLC25A47.
- chr14:105,140,982–105,181,323, 4 genes: JAG2, MIR6765, AL512356.1, NUDT14.
- chr15:41,828,092–41,848,155, 3 genes (within-gene range 0–2): JMJD7, JMJD7-PLA2G4B, PLA2G4B.
- chr15:41,851,913–41,852,029, 1 gene (within-gene range 0–2): RNA5SP393.
- chr17:17,813,480–17,813,931, 2 genes (within-gene range 0–2): MIR6777, MIR33B.
- chr19:18,868,545–18,934,397, 6 genes (within-gene range 0–1): GDF1, CERS1, AC005197.1, COPE, AC002985.1, DDX49.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 80 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:37,575,587–38,589,812, 14 genes, copy number 7: ZNF970P, AK6P2, CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359, TUBB8P5, AC117372.1, NF1P12, Y_RNA, ALG10B, AC087897.1, AC087897.2.
- chr12:54,121,277–54,189,008, 1 gene, copy number 15 (within-gene range 1–15): SMUG1.
- chr12:54,145,069–54,351,846, 14 genes, copy number 15: AC023794.5, AC023794.4, AC023794.1, CBX5, MIR3198-2, RN7SL390P, SCAT2, AC078778.1, HNRNPA1, NFE2, COPZ1, RNU6-950P, MIR148B, RN7SL744P.
- chr12:57,546,026–57,896,846, 31 genes, copy number 27 (within-gene range 2–27): KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3.
- chr14:31,025,106–31,488,039, 14 genes, copy number 16 (within-gene range 1–16): AP4S1, HECTD1, RPL21P5, RNU6-541P, Y_RNA, AL136418.1, Y_RNA, HEATR5A, ATP5MC1P2, AL139353.1, AL139353.2, DTD2, AL163973.1, GPR33.
- chr14:32,329,298–32,837,684, 4 genes, copy number 15: AKAP6, AL136298.1, RN7SL660P, MTCO1P2.
- chr21:44,107,373–44,210,114, 2 genes, copy number 5–8 (within-gene range 1–8): PWP2, GATD3A.

Autosomal genes at a single copy (total copy number 1): 14,951. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
